Somatic mutation profile of tumor specimen 0DR9CF from CCDI case PBCGIB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (172 days).
Specimen 0DR9CF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22deceea-d863-496e-b102-a0801976cd49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR9CX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/742e296b-3944-431f-8e4a-84dcb3516f56

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HAUS5 | c.219G>A p.Q73= | Splice Region (SNP) | VAF 152/1606 reads (9%) | catalogued as rs868326616; called by muse, mutect2
- PRAMEF9 | c.1433G>A p.C478Y | Missense Mutation (SNP) | VAF 203/858 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314700784; called by muse, mutect2, varscan2
- EGLN1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 48/1979 reads (2%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 68/1993 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- SEC23IP | c.1101+86G>A | Intron (SNP) | VAF 59/420 reads (14%) | catalogued as rs760825158; called by muse, mutect2, varscan2
